Somatic mutation profile of tumor specimen TCGA-IE-A4EH-01A (aliquot TCGA-IE-A4EH-01A-11D-A24N-09) from TCGA case TCGA-IE-A4EH, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Corpus uteri; Age at diagnosis: 35.2 years (12,871 days).
Specimen TCGA-IE-A4EH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8a14e3c-6a63-4b47-93a2-64b863525645.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IE-A4EH-10A (Blood Derived Normal), aliquot TCGA-IE-A4EH-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d92ffdfa-f9f7-4f23-804c-6ecd0b203cc5

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 50/53 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANAPC1 | c.5306A>T p.D1769V | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100594954; called by muse, mutect2, varscan2
- C14orf39 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100407910; called by muse, mutect2, varscan2
- COL6A6 | c.3238G>A p.G1080S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs759591819, COSV62021952; called by muse, mutect2, varscan2
- DRD1 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM086309, COSV101192503; called by muse, mutect2, varscan2
- EPN2 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs776952887, COSV59064127; called by muse, mutect2, varscan2
- KIF4A | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100979598; called by muse, mutect2, varscan2
- KIF9 | c.1288A>T p.S430C | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.428); catalogued as COSV99646890; called by muse, mutect2, varscan2
- LATS2 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as COSV101231641; called by muse, mutect2, varscan2
- LRP2 | c.13009A>G p.I4337V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99789594; called by muse, mutect2, varscan2
- NCK2 | c.41C>G p.T14S | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.49); PolyPhen benign (0.098); catalogued as COSV99256484; called by muse, mutect2, varscan2
- PSMB11 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs533259463, COSV57458527; called by mutect2, varscan2
- RAD54L2 | c.1164A>C p.K388N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV99621633; called by muse, mutect2, varscan2
- RHOH | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.14); catalogued as COSV101110573; called by muse, mutect2
- RRP1B | c.1849G>T p.G617W | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV61479345; called by muse, mutect2
- RTL9 | c.2099A>T p.Q700L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101511752; called by muse, mutect2, varscan2
- PPM1B | c.924dup p.D309Rfs*6 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- CLCA2 | c.1980A>G p.G660= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100991632; called by muse, mutect2, varscan2
- COL4A2 | c.5010C>T p.N1670= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV100847428; called by muse, mutect2
- ELOA2 | c.1836G>A p.P612= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs756246313, COSV55294629; called by muse, mutect2, varscan2
- FANCG | c.420C>T p.H140= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs764566651, COSV62720094; called by muse, mutect2, varscan2
- MICU2 | c.1224A>G p.Q408= | Silent (SNP) | VAF 58/122 reads (48%) | catalogued as COSV101212467; called by muse, mutect2, varscan2
- PODXL | c.1417C>T p.L473= (on ENST00000378555 / NM_001018111.3; = p.L441= on NM_005397.4) | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100539641; called by muse, mutect2
- SALL1 | c.3930C>A p.R1310= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- SETD5 | c.312C>T p.L104= | Silent (SNP) | VAF 52/96 reads (54%) | catalogued as rs376494447, COSV100201193; ClinVar: likely benign; called by muse, mutect2, varscan2
- BIRC8 | n.1071C>T | RNA (SNP) | VAF 11/34 reads (32%) | catalogued as rs375698355; called by muse, mutect2, varscan2
